Somatic mutation profile of tumor specimen TCGA-V4-A9EI-01A (aliquot TCGA-V4-A9EI-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EI, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 78.2 years (28,562 days).
Specimen TCGA-V4-A9EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec707bb2-8f55-4831-9a00-02c388406f70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EI-10A (Blood Derived Normal), aliquot TCGA-V4-A9EI-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f9934b4-14a4-45c6-914d-7c4ebdd468a8

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MC2R | c.289A>T p.S97C | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1300489219; called by muse, mutect2, varscan2
- NIN | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1185253688, COSV55388207; called by muse, mutect2, varscan2
- NRXN1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as rs202205785; called by muse, varscan2
- OR4K1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53461795; called by muse, mutect2, varscan2
- PCDHA9 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs782015840; called by muse, mutect2, varscan2
- PER1 | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 67/81 reads (83%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.012); catalogued as rs535590026; called by muse, mutect2, varscan2
- ZNF20 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV61998666; called by muse, mutect2, varscan2
- ANKRD27 | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BAP1 | c.2015_2024del p.D672Afs*17 | Frame Shift Del (DEL) | VAF 19/27 reads (70%) | called by mutect2, pindel, varscan2
- BTBD7 | c.730A>C p.M244L | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- DYNC1H1 | c.9899A>G p.K3300R | Missense Mutation (SNP) | VAF 87/325 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DYNC2H1 | c.11344T>A p.L3782I | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MYO7B | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- PDXDC1 | c.641A>T p.H214L | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- POLK | c.2057A>C p.Y686S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPDL1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- THSD7B | c.3010A>C p.S1004R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.68279C>T p.A22760V (on ENST00000591111; = p.A15336V on NM_003319.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- UTP14C | c.2206G>T p.V736L | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PCCA | c.1740G>A p.V580= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- RYR2 | c.12552G>A p.E4184= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs1300867476, COSV63678964; called by muse, mutect2, varscan2
- SBNO2 | c.1524G>A p.L508= | Silent (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- NACA | c.71-4736A>C | Intron (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
